Somatic mutation profile of tumor specimen TARGET-10-PATLRZ-09A (aliquot TARGET-10-PATLRZ-09A-01D) from TARGET case TARGET-10-PATLRZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.0 years (5,105 days).
Specimen TARGET-10-PATLRZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 361f3e08-a31c-4461-87b9-652480c09b7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLRZ-10A (Blood Derived Normal), aliquot TARGET-10-PATLRZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe5855bc-fd11-41d6-9520-7562a7d15757

The open-access MAF lists 35 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, RNA 3, 3'Flank 2, Frame Shift Ins 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.440T>C p.V147A (on ENST00000611781; = p.V91A on NM_052997.2) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as COSV64603093; called by muse, mutect2, varscan2
- ASPHD2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs200334205, COSV53217884; called by muse, mutect2, varscan2
- BCL11B | c.1394C>T p.S465L (on ENST00000357195 / NM_001282237.2; = p.S394L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1213744482, COSV61732956; called by mutect2, varscan2
- CDCA7 | c.524G>A p.R175Q (on ENST00000347703 / NM_145810.3; = p.R254Q on NM_031942.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs200556185, COSV60719784; called by muse, mutect2, varscan2
- CFAP47 | c.4134G>C p.K1378N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.244); catalogued as COSV57971866; called by muse, mutect2
- DNM2 | c.285_286insTTATTATCCCA p.E96Lfs*39 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as COSV58956729; called by mutect2, pindel, varscan2
- DOCK1 | c.1562C>A p.S521Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV54728561; called by muse, mutect2, varscan2
- FAM118A | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.972); catalogued as COSV53415954; called by muse, mutect2, varscan2
- FOXG1 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57394865; called by muse, mutect2, varscan2
- JPH2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV65901663; called by muse, mutect2, varscan2
- MMP2 | c.1769G>A p.R590K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV54598835; called by muse, mutect2, varscan2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- PATJ | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs369693931; called by muse, mutect2
- PBOV1 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV52449526; called by muse, mutect2, varscan2
- PHF6 | c.309C>G p.Y103* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as COSV59699031; called by muse, mutect2, varscan2
- PLXNA1 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs143376196; called by muse, mutect2, varscan2
- ROBO1 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.241); catalogued as COSV71391438; called by muse, mutect2, varscan2
- RPS3 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV53704068; called by muse, mutect2, varscan2
- RYR2 | c.12944G>T p.G4315V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63658108, COSV63667834; called by muse, mutect2, varscan2
- UBE2QL1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV67715333; called by muse, mutect2, varscan2
- ZNF407 | c.509dup p.K171Efs*4 | Frame Shift Ins (INS) | VAF 36/91 reads (40%) | catalogued as rs773084494; called by mutect2, pindel, varscan2
- ATP13A1 | c.1245G>A p.L415= | Silent (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- EPHA7 | c.726G>A p.A242= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs148725762; called by muse, mutect2, varscan2
- HID1 | c.1290C>T p.S430= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs151291954, COSV59351794; called by muse, mutect2, varscan2
- KSR1 | c.771C>T p.S257= (on ENST00000644974 / NM_001367810.1; = p.S120= on NM_014238.2) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs553599793, COSV99259481; called by muse, mutect2, varscan2
- MITF | c.516G>A p.P172= (on ENST00000448226 / NM_006722.3; = p.P66= on NM_000248.4) | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs370367869, COSV58834152; called by muse, mutect2, varscan2
- PCDHGA5 | c.162G>A p.L54= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- PPP1R8 | c.84T>C p.H28= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.708C>T p.C236= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs1187942863, COSV60291777; called by muse, mutect2, varscan2
- AC092810.1 | n.139G>C | RNA (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- AL590867.2 | n.52C>G | RNA (SNP) | VAF 6/42 reads (14%) | catalogued as rs375853555; called by mutect2, varscan2
- COL5A1 | chr9:134849498 ins GGGATCACACCTCCCAGGAACCAT | 3'Flank (INS) | VAF 6/40 reads (15%) | called by pindel, varscan2*
- FAM153CP | chr5:178055744 C>T | 3'Flank (SNP) | VAF 15/41 reads (37%) | catalogued as rs796546309; called by muse, varscan2
- LRRC37A16P | n.3360T>C | RNA (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- MIR124-2 | chr8:64377439 G>A | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
